Gene-level copy-number profile of tumor specimen TARGET-40-PALZGU-01A from TARGET case TARGET-40-PALZGU, project TARGET-OS (Osteosarcoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Osteosarcoma, NOS; Tissue or organ of origin: Long bones of lower limb and associated joints; Age at diagnosis: 15.3 years (5,603 days).
Specimen TARGET-40-PALZGU-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TARGET-OS.06974a6a-0b86-5913-8595-9863ab28aed5.gene_level_copy_number.v36.tsv, workflow ASCAT2 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TARGET-40-PALZGU-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 406 have no estimate.
https://portal.gdc.cancer.gov/files/b9fdbeeb-b57d-47d4-a1e4-03f4ab940b73

Most common (modal) total copy number across autosomal genes: 6 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 13; copy number 2: 2,407; copy number 3: 18,963; copy number 4: 1,964; copy number 5: 7,993; copy number 6: 21,259; copy number 7: 2,213; copy number 8: 3,027; copy number 9: 729; copy number 10: 249; copy number 11: 139; copy number 12: 87; copy number 13: 246; copy number 14: 61; copy number 15: 221; copy number 16: 202; copy number 17: 53; copy number 18: 11; copy number 19: 280; copy number 20: 16; copy number 21: 1; copy number 22: 8; copy number 23: 33; copy number 24: 32; copy number 28: 10.

Homozygous deletions (total copy number 0; autosomes only): 13 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:116,921,328–117,027,039, 4 genes: AC069504.1, LINC00901, RNU5E-8P, PTMAP8.
- chr5:165,349,030–166,155,439, 6 genes (within-gene range 0–4): AC008415.1, RN7SKP60, AC008562.1, AC008489.1, RPL7P20, AC114321.1.
- chr7:147,080,934–147,167,572, 3 genes: CNTNAP2-AS1, DUTP3, RANP2.

Amplified relative to the modal value (total copy number ≥ 13, i.e. more than twice the modal value of 6; autosomes only): 1,174 genes in 26 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:558,153–578,145, 1 gene, copy number 17 (within-gene range 12–17): AC093326.1.
- chr2:950,849–1,744,852, 10 genes, copy number 14–18 (within-gene range 12–18): SNTG2, AC114808.1, AC114808.2, AC108462.1, AC105450.1, TPO, AC141930.1, AC141930.2, AC144450.1, PXDN.
- chr2:1,795,525–1,828,667, 2 genes, copy number 14: AC093390.2, AC093390.1.
- chr2:4,827,001–4,827,084, 1 gene, copy number 13: AC092169.1.
- chr2:6,615,389–6,651,104, 3 genes, copy number 15: MIR7515HG, AC097517.1, MIR7515.
- chr2:11,833,926–12,702,913, 5 genes, copy number 14 (within-gene range 12–14): MIR3681HG, MIR4262, SNORD18, MIR3681, RNU6-843P.
- chr2:102,873,183–102,895,780, 1 gene, copy number 15: LINC01796.
- chr2:113,888,203–114,007,304, 6 genes, copy number 14: AC110769.2, ACTR3, AC110769.3, LINC01191, AC110769.1, U3.
- chr7:4,130,181–5,606,655, 39 genes, copy number 15: AC017000.1, CYP3A54P, AC072054.1, FOXK1, AC092428.1, AP5Z1, MIR4656, AC092610.1, RADIL, Y_RNA, PAPOLB, RPL22P16, MMD2, RNF216P1, AC092032.2, RBAK-RBAKDN, AC092032.3, AC092032.1, SPDYE19P, RBAK, RBAKDN, OR10AH1P, ZNF890P, RNU6-215P, WIPI2, SLC29A4, TNRC18, AC093620.1, AC092171.1, AC092171.4, AC092171.3, AC092171.5, FBXL18, AC092171.2, MIR589, ACTB, AC006483.2, AC006483.1, FSCN1.
- chr7:10,449,820–16,502,504, 52 genes, copy number 13 (within-gene range 6–13): MGC4859, HSPA8P8, AC009945.1, AC004415.1, Y_RNA, NDUFA4, AC007029.1, PHF14, RPL23AP52, AC004160.1, NPM1P11, THSD7A, AC004160.2, THRAP3P3, TMEM106B, VWDE, AC013470.3, AC013470.2, SSBL5P, TAS2R2P, AC013470.1, AC005281.1, SCIN, AC011891.2, AC011891.3, ARL4A, AC011891.1, AC011287.1, RN7SKP228, RBMX2P4, AC011287.2, AC005019.2, AC005019.1, ETV1, Y_RNA, RPL6P21, DGKB, EEF1A1P26, AC006150.1, GTF3AP5, AC006458.1, AGMO, MEOX2, AC005550.2, LINC02587, AC005550.1, RPL36AP26, AC006041.2, AC006041.1, CRPPA, RPL36AP29, CRPPA-AS1.
- chr7:16,471,184–16,471,373, 1 gene, copy number 13: AC005014.3.
- chr8:103,398,635–144,261,940, 549 genes, copy number 13–24 (within-gene range 8–24) (broad region; genes not listed).
- chr9:6,328,375–6,645,729, 7 genes, copy number 14: TPD52L3, UHRF2, AL133480.1, GLDC, RN7SL25P, AL353718.1, RPL23AP57.
- chr10:34,965,069–35,090,642, 4 genes, copy number 15: PRDX2P2, LINC02635, CUL2, MIR3611.
- chr13:96,090,839–96,839,562, 1 gene, copy number 14 (within-gene range 8–14): HS6ST3.
- chr13:96,427,229–96,574,499, 2 genes, copy number 14: MIR4501, AMMECR1LP1.
- chr13:96,941,281–102,904,000, 117 genes, copy number 13–17 (within-gene range 12–17) (broad region; genes not listed).
- chr13:103,343,660–103,444,968, 3 genes, copy number 15: AL162717.1, LINC01309, ATP6V1G1P7.
- chr13:106,489,745–113,658,198, 124 genes, copy number 13–23 (broad region; genes not listed).
- chr14:105,785,505–106,443,583, 115 genes, copy number 16 (broad region; genes not listed).
- chr15:80,404,350–80,663,878, 7 genes, copy number 14 (within-gene range 6–14): ARNT2, AC016705.1, AC016705.3, AC108451.1, AC108451.2, MIR5572, RNU6-380P.
- chr15:80,693,216–80,693,707, 1 gene, copy number 14: AC023302.1.
- chr15:88,459,477–88,875,353, 14 genes, copy number 16: MRPL46, AC013489.1, MRPS11, AC013489.3, DET1, AC013489.2, LINC01586, MIR1179, MIR7-2, MIR3529, AEN, ISG20, AC103982.1, ACAN.
- chr15:90,001,324–90,883,458, 43 genes, copy number 15: ZNF710, MIR3174, AC087284.1, ZNF710-AS1, U7, IDH2, IDH2-DT, SEMA4B, RN7SL346P, RPS12P26, CIB1, GDPGP1, AC091167.7, TTLL13P, AC091167.2, NGRN, AC091167.6, AC091167.1, AC091167.3, AC091167.5, AC091167.4, GOLGA2P8, RN7SL736P, GABARAPL3, GABARAPL3, ZNF774, NDUFA3P4, IQGAP1, AC018946.1, CRTC3, AC103739.1, AC103739.2, CRTC3-AS1, AC103739.3, HSPE1P3, AC021422.1, LINC01585, BLM, SNORD18, AC124248.2, AC124248.1, RN7SL363P, FURIN.
- chr16:77,104,260–80,563,354, 58 genes, copy number 16–28 (within-gene range 9–28): AC106733.1, MON1B, SYCE1L, AC009139.2, VN2R10P, AC009139.1, ADAMTS18, AC025284.1, LINC02131, AC092724.1, NUDT7, AC092134.1, AC092134.3, VAT1L, AC092134.2, PPIAP50, AC079414.1, CLEC3A, KRT8P22, AC079414.2, WWOX, AC079414.3, AC009044.1, WWOX-AS1, AC106743.1, LSM3P5, AC046158.1, AC046158.4, AC046158.2, AC046158.3, AC009141.1, RPS3P7, AC136603.1, AC027279.4, AC027279.1, AC027279.3, AC027279.2, AC009145.4, AC009145.3, AC009145.1, AC009145.2, AC092376.2, AC092376.3, AC092376.1, RNA5SP431, AC084064.1, MAF, AC009159.2, AC009159.3, AC009159.1, AC009159.4, LINC01229, MAFTRR, LINC01228, AC092130.1, AC022166.1, AC105411.1, AC022166.2.
- chr21:28,928,144–29,073,797, 8 genes, copy number 16: LTN1, RPL23P2, RWDD2B, AF129075.2, USP16, CCT8, AF129075.1, AF129075.3.

Autosomal genes at a single copy (total copy number 1): 0. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
